Gene-level copy-number profile of tumor specimen C3N-01844-03 from CPTAC case C3N-01844, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 63.1 years (23,051 days).
Specimen C3N-01844-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cd6c997f-7367-4836-875e-f356632be7df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01844-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/54122bc3-f6ca-49b4-9371-824bfa6dc7dd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 8,551; copy number 2: 40,268; copy number 3: 7,691; copy number 4: 1,025; copy number 5: 55; copy number 6: 767; copy number 7: 4; copy number 8: 26.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–1): RN7SL5P.
- chr11:88,504,576–89,065,945, 3 genes (within-gene range 0–1): GRM5-AS1, GRM5, RNU6-16P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 852 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,461,221–144,068,350, 26 genes, copy number 8: AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D.
- chr1:153,606,886–153,986,358, 36 genes, copy number 6: S100A16, S100A14, S100A13, AL162258.1, S100A1, AL162258.2, CHTOP, SNAPIN, ILF2, NPR1, MIR8083, RN7SL372P, GEMIN2P1, Y_RNA, INTS3, AL513523.4, AL513523.3, SLC27A3, Y_RNA, GATAD2B, AL513523.2, AL513523.1, AL831737.1, AL358472.5, DENND4B, CRTC2, SLC39A1, AL358472.7, MIR6737, AL358472.4, AL358472.3, CREB3L4, JTB, AL358472.6, AL358472.2, RAB13.
- chr1:164,555,584–187,686,628, 445 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:242,882,066–248,101,103, 141 genes, copy number 6 (broad region; genes not listed).
- chr9:12,134–215,893, 12 genes, copy number 5 (within-gene range 3–5): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1.
- chr9:39,886,861–40,106,611, 6 genes, copy number 5: RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3.
- chr11:67,627,938–69,171,564, 58 genes, copy number 6: NUDT8, TBX10, ACY3, AP003385.1, ALDH3B2, RPL37P2, UNC93B5, OR7E145P, OR7E11P, AP003385.5, AP003385.2, AP003385.4, ALG1L8P, FAM86C2P, ENPP7P7, AP003716.1, LINC02754, RNU6-46P, RPS3AP40, AC004923.1, AC004923.2, AC004923.3, OR7E1P, UNC93B1, ALDH3B1, AC004923.4, NDUFS8, MIR7113, MIR4691, TCIRG1, MIR6753, AP002807.1, CHKA, AP002992.1, KMT5B, C11orf24, LRP5, PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38.
- chr11:69,641,156–71,252,577, 37 genes, copy number 6: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:73,974,672–74,171,210, 5 genes, copy number 5 (within-gene range 3–5): UCP2, AP003717.2, AP003717.3, UCP3, C2CD3.
- chr11:74,988,279–77,637,794, 76 genes, copy number 5–6 (broad region; genes not listed).
- chr11:80,957,317–82,733,864, 10 genes, copy number 5–7: AP003398.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B.

Autosomal genes at a single copy (total copy number 1): 7,502. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
